Somatic mutation profile of tumor specimen MP2PRT-PARRLJ-TMP1-A (aliquot MP2PRT-PARRLJ-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARRLJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (825 days).
Specimen MP2PRT-PARRLJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 630a666d-e692-4422-9a24-3ac27242d3d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARRLJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARRLJ-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea3b3739-75c9-4269-a62c-737962cdb6e1

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CECR2 | c.1802G>A p.R601H (on ENST00000342247 / NM_001290047.2; = p.R418H on NM_001290046.1) | Missense Mutation (SNP) | VAF 220/488 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs565809706; called by muse, mutect2, varscan2
- COL6A6 | c.4588C>T p.R1530C | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs377422894; called by muse, mutect2, varscan2
- PARN | c.1075A>G p.K359E | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs192893173; called by muse, mutect2, varscan2
- EFCAB1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA5 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- KLRD1 | c.340T>C p.F114L | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
